Somatic mutation profile of tumor specimen TCGA-D8-A1XG-01A (aliquot TCGA-D8-A1XG-01A-11D-A14G-09) from TCGA case TCGA-D8-A1XG, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 86.9 years (31,748 days).
Specimen TCGA-D8-A1XG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f6e79d8-b897-4cb4-998e-18be4c8e547e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1XG-10A (Blood Derived Normal), aliquot TCGA-D8-A1XG-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58d2c6b5-85c2-4c4c-b091-867019c7c6f1

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Frame Shift Del 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM12 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767462610, COSV64103375, COSV64115761; called by muse, mutect2, varscan2
- AFAP1L1 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV57048150; called by muse, mutect2, varscan2
- ANGPTL2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs768957923, COSV52234275; called by muse, mutect2, varscan2
- C3 | c.1452G>T p.E484D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV55569960, COSV55582497; called by mutect2, varscan2
- CLDN22 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV60109944; called by muse, mutect2, varscan2
- ELP4 | c.852G>C p.K284N (on ENST00000350638; = p.K283N on NM_019040.5) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV100635374, COSV63359030; called by muse, mutect2, varscan2
- LTBP2 | c.2105G>A p.G702D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1401080194, COSV56209431, COSV56214969; called by muse, mutect2, varscan2
- MCTP1 | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.436); catalogued as COSV72406883; called by muse, mutect2, varscan2
- PHLDB2 | c.1608G>T p.R536S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV67316652; called by muse, mutect2, varscan2
- SEMA5B | c.900C>A p.F300L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as COSV52109767, COSV99533524; called by muse, mutect2, varscan2
- SETD7 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs1300856437, COSV56802337; called by muse, mutect2, varscan2
- SLC22A10 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs749509766, COSV60420444, COSV60420629; called by muse, mutect2, varscan2
- FOXA1 | c.99_105del p.M34Qfs*6 | Frame Shift Del (DEL) | VAF 24/87 reads (28%) | called by mutect2, pindel, varscan2
- HSPD1 | c.1619_1628del p.T540Kfs*3 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- NIPAL2 | c.667_668del p.V223Yfs*17 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- FBN2 | c.8226G>A p.G2742= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs767683286, COSV52548510; called by muse, mutect2, varscan2
- NPAS3 | c.1749G>A p.S583= (on ENST00000356141 / NM_001164749.2; = p.S551= on NM_022123.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1269347334, COSV60866377; called by muse, varscan2
- PPP1CA | c.579A>T p.T193= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV56705574; called by muse, mutect2, varscan2
- PTPN23 | c.2166C>A p.A722= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV55546379; called by muse, mutect2
- RBL1 | c.1113G>A p.L371= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs765989667, COSV60334380; called by muse, mutect2, varscan2
- ST6GAL2 | c.1422C>T p.D474= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs145567871; called by muse, mutect2, varscan2
- ATP2B2 | c.*266C>T | 3'UTR (SNP) | VAF 37/94 reads (39%) | catalogued as rs758884069, COSV59508656; called by muse, mutect2, varscan2
